Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5717, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5717-01A (Primary Tumor).

TCGA-CG-5717

*** Diagnosis(es): ***

Resection specimen of the distal esophagus and proximal stomach with an almost circular, 3.5 cm-long carcinoma of the esophagogastric junction taking up about two-thirds of the stomach, of the histological type of a poorly differentiated, predominantly solid adenocarcinoma. Invasive tumor dissemination within all esophageal and gastric wall layers into the adjacent fatty tissue. Gastric mucosa of the corpus and antrum-corpus junction with minimal, non-florid chronic gastritis of the superficial type. No evidence of *Helicobacter pylori*.

Oral and aboral resection margin tumor-free.

Three of 26 lymph nodes with metastases from the carcinoma described.

Therefore tumor stage assuming a gastric localization (cardia carcinoma) pT2b; assuming a primary localization of the distal esophagus pT3 pN1 (3/26).

Source: NCI Genomic Data Commons file 306d6ee7-13f6-430c-aab9-0a98a17afb4f (TCGA-CG-5717.532F48C5-B31B-46D9-A943-F9F0EDCA6BFF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).